Somatic mutation profile of tumor specimen MMRF_2159_1_BM_CD138pos (aliquot MMRF_2159_1_BM_CD138pos_T1_KHS5U_L08728) from MMRF case MMRF_2159, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.3 years (21,649 days).
Specimen MMRF_2159_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12c4565c-5035-405f-88e0-936eb9189967.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2159_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2159_1_PB_Whole_C3_KHS5U_L08727; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/435b8092-8c57-4954-bb33-a53cafcb8e20

The open-access MAF lists 88 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 22, Silent 12, Intron 11, 5'Flank 4, 5'UTR 4, Splice Site 2, 3'Flank 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD163 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.297); catalogued as rs1289477810; called by muse, mutect2
- COL8A1 | c.1606G>A p.G536R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175177004; called by muse, mutect2, varscan2
- EZR | c.4C>G p.P2A | Missense Mutation (SNP) | VAF 206/271 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs141238344; called by muse, mutect2, varscan2
- HMGXB3 | c.3896G>A p.R1299H (on ENST00000613459; = p.R1053H on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs773229887; called by muse, mutect2, varscan2
- IQCN | c.2831G>A p.R944H | Missense Mutation (SNP) | VAF 84/179 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs200997372, COSV62748744; called by muse, mutect2, varscan2
- KCNT2 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.034); catalogued as COSV54076938; called by muse, mutect2, varscan2
- MYO1E | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 28/53 reads (53%) | catalogued as rs543195936; called by muse, mutect2, varscan2
- PCNX4 | c.788C>T p.P263L (on ENST00000406854 / NM_001330177.2; = p.P29L on NM_022495.5) | Missense Mutation (SNP) | VAF 24/486 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs911388523; called by muse, mutect2
- PLD1 | c.2548A>G p.M850V | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV60565152; called by muse, mutect2, varscan2
- SYT7 | c.1191G>T p.Q397H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1307341700; called by mutect2, varscan2
- TBC1D28 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs199673813, COSV61507684; called by muse, mutect2, varscan2
- ZNF616 | c.1928G>C p.S643T | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs35304389; called by muse, mutect2, varscan2
- ANK3 | c.10913C>G p.T3638S | Missense Mutation (SNP) | VAF 9/229 reads (4%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); called by muse, mutect2
- ASB18 | c.1312A>G p.K438E | Missense Mutation (SNP) | VAF 16/359 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.254); called by muse, mutect2
- ATP5MC3 | c.386T>A p.L129H | Missense Mutation (SNP) | VAF 292/908 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTBD8 | c.5369C>G p.T1790S (on ENST00000636805 / NM_001376131.1; = p.T1277S on NM_015237.4) | Missense Mutation (SNP) | VAF 18/738 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CFTR | c.2110C>A p.P704T | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2
- CYP2A7 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DPPA3 | c.116A>T p.K39M | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- FIP1L1 | c.1406G>A p.R469K | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.745); called by muse, varscan2
- GLB1L2 | c.554T>A p.L185H | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); called by muse, mutect2
- HSPG2 | c.2320G>A p.D774N | Missense Mutation (SNP) | VAF 80/181 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IFT172 | c.4612_4634del p.A1538Cfs*34 | Frame Shift Del (DEL) | VAF 44/160 reads (28%) | called by mutect2, pindel, varscan2
- JAK1 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- KATNAL2 | c.814T>C p.Y272H (on ENST00000356157 / NM_001353899.1; = p.Y200H on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/290 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- LRRC4C | c.281A>G p.N94S | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2
- MATK | c.242G>T p.C81F (on ENST00000310132 / NM_139355.3; = p.C82F on NM_002378.4) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- PPP1CC | c.874T>A p.S292T | Missense Mutation (SNP) | VAF 41/727 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); called by muse, mutect2
- PRKCG | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 169/440 reads (38%) | called by muse, mutect2, varscan2
- PRKD2 | c.1121+1G>A p.X374_splice | Splice Site (SNP) | VAF 14/422 reads (3%) | called by muse, mutect2
- PTK2 | c.668T>G p.L223R | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- RPRD1B | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- STXBP2 | c.581G>C p.G194A | Missense Mutation (SNP) | VAF 17/457 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.223); called by muse, mutect2
- TRBV10-2 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ANXA6 | c.1101A>C p.A367= | Silent (SNP) | VAF 76/190 reads (40%) | called by muse, mutect2, varscan2
- BNC2 | c.1830G>A p.E610= | Silent (SNP) | VAF 8/218 reads (4%) | called by muse, mutect2
- COL11A1 | c.4194G>A p.Q1398= | Silent (SNP) | VAF 53/117 reads (45%) | catalogued as COSV62179427; called by muse, mutect2, varscan2
- HK2 | c.231C>T p.H77= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs755935708, COSV51877583; called by muse, mutect2, varscan2
- IGLC2 | c.312A>G p.E104= | Silent (SNP) | VAF 82/284 reads (29%) | catalogued as rs750943388; called by muse, mutect2, varscan2
- IGLC3 | c.312A>G p.E104= | Silent (SNP) | VAF 39/195 reads (20%) | catalogued as rs1367281122; called by muse, mutect2, varscan2
- KIAA1109 | c.4497G>A p.V1499= | Silent (SNP) | VAF 199/542 reads (37%) | called by muse, mutect2, varscan2
- LIPF | c.562C>T p.L188= | Silent (SNP) | VAF 206/496 reads (42%) | called by muse, mutect2, varscan2
- MC1R | c.258G>C p.L86= | Silent (SNP) | VAF 36/532 reads (7%) | called by muse, mutect2
- RSPH10B | c.1656C>T p.Y552= | Silent (SNP) | VAF 54/194 reads (28%) | catalogued as rs777700625; called by muse, mutect2, varscan2
- TENM3 | c.873A>C p.L291= | Silent (SNP) | VAF 173/439 reads (39%) | called by muse, mutect2, varscan2
- TRIM16L | c.174C>T p.A58= | Silent (SNP) | VAF 100/211 reads (47%) | catalogued as rs1465277838, COSV67459499; called by muse, mutect2, varscan2
- ADCY2 | c.-68C>A | 5'UTR (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- AGFG1 | c.*2254T>G | 3'UTR (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- AGTR2 | c.*701A>G | 3'UTR (SNP) | VAF 66/137 reads (48%) | called by muse, mutect2, varscan2
- ARAP2 | c.*1479G>C | 3'UTR (SNP) | VAF 69/216 reads (32%) | called by muse, mutect2, varscan2
- ARL13B | c.-251C>T | 5'UTR (SNP) | VAF 114/355 reads (32%) | catalogued as rs1465885056; called by muse, mutect2, varscan2
- ARPC5L | c.*722T>G | 3'UTR (SNP) | VAF 47/124 reads (38%) | called by muse, mutect2, varscan2
- ASRGL1 | c.*1049G>A | 3'UTR (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- ATF7 | c.*122+977C>G | Intron (SNP) | VAF 47/148 reads (32%) | called by muse, mutect2, varscan2
- CABP1 | c.655-4468G>A | Intron (SNP) | VAF 76/186 reads (41%) | called by muse, mutect2, varscan2
- CCND1 | c.*2692_*2695del | 3'UTR (DEL) | VAF 123/370 reads (33%) | called by mutect2, pindel, varscan2
- DIS3 | c.*3475A>T | 3'UTR (SNP) | VAF 77/142 reads (54%) | called by muse, mutect2, varscan2
- ELAVL4 | chr1:50201404 A>C | 3'Flank (SNP) | VAF 8/195 reads (4%) | catalogued as rs1393747302; called by muse, mutect2
- EN1 | c.*672C>G | 3'UTR (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- FAM114A2 | c.*2511T>A | 3'UTR (SNP) | VAF 84/184 reads (46%) | called by muse, mutect2, varscan2
- FAN1 | c.1943+135C>G | Intron (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2
- FASLG | c.*289C>A | 3'UTR (SNP) | VAF 41/150 reads (27%) | called by muse, mutect2, varscan2
- GRAMD1B | c.*1893G>A | 3'UTR (SNP) | VAF 67/188 reads (36%) | called by muse, mutect2, varscan2
- H3C3 | chr6:26044163 G>C | 5'Flank (SNP) | VAF 7/114 reads (6%) | catalogued as rs1341738863; called by muse, mutect2
- ICAM3 | c.649+50C>T | Intron (SNP) | VAF 145/420 reads (35%) | called by muse, mutect2, varscan2
- IER3IP1 | c.*74A>G | 3'UTR (SNP) | VAF 141/380 reads (37%) | called by muse, mutect2, varscan2
- ITGA2 | c.*1055C>T | 3'UTR (SNP) | VAF 67/172 reads (39%) | called by muse, mutect2, varscan2
- ITGAV | c.186-1675C>A | Intron (SNP) | VAF 20/618 reads (3%) | called by muse, mutect2
- KRT10 | c.1748+15G>A | Intron (SNP) | VAF 126/305 reads (41%) | called by muse, varscan2
- METAP2 | chr12:95473886 del T | 5'Flank (DEL) | VAF 26/86 reads (30%) | called by pindel, varscan2
- METAP2 | chr12:95473892 T>C | 5'Flank (SNP) | VAF 38/98 reads (39%) | called by muse, varscan2
- MYOD1 | c.*353G>A | 3'UTR (SNP) | VAF 7/181 reads (4%) | catalogued as rs1258058027; called by muse, mutect2
- OXSR1 | chr3:38165498 G>T | 5'Flank (SNP) | VAF 34/67 reads (51%) | catalogued as rs1175267081; called by muse, mutect2, varscan2
- PGM3 | c.*3810A>G | 3'UTR (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- PLAAT3 | c.-33G>A | 5'UTR (SNP) | VAF 101/268 reads (38%) | catalogued as rs934186572; called by muse, mutect2, varscan2
- RAB27B | c.*1845C>G | 3'UTR (SNP) | VAF 10/191 reads (5%) | called by muse, mutect2
- RNF185 | c.363+61T>A | Intron (SNP) | VAF 46/133 reads (35%) | called by muse, mutect2, varscan2
- RPL36A | c.177+310C>A | Intron (SNP) | VAF 143/329 reads (43%) | called by muse, mutect2, varscan2
- SEPSECS | c.*2505C>T | 3'UTR (SNP) | VAF 41/127 reads (32%) | called by muse, mutect2, varscan2
- SGCB | c.*515G>C | 3'UTR (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2
- SH2D1A | c.*123A>G | 3'UTR (SNP) | VAF 11/359 reads (3%) | called by muse, mutect2
- SRSF7 | c.573-157A>C | Intron (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- TMEM138 | c.300+128C>G | Intron (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- TMEM184B | c.359-114C>G | Intron (SNP) | VAF 21/49 reads (43%) | catalogued as COSV62672028; called by muse, mutect2, varscan2
- TOP1 | c.*81G>A | 3'UTR (SNP) | VAF 16/513 reads (3%) | catalogued as rs1281364957; called by muse, mutect2
- TSHZ2 | c.-543A>T | 5'UTR (SNP) | VAF 4/31 reads (13%) | catalogued as rs1389282121; called by muse, mutect2
- WAPL | c.*338G>A | 3'UTR (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- WDR3 | c.*656T>A | 3'UTR (SNP) | VAF 15/39 reads (38%) | catalogued as rs1252856661; called by muse, mutect2, varscan2
